Somatic mutation profile of tumor specimen TCGA-BF-AAP7-01A (aliquot TCGA-BF-AAP7-01A-11D-A401-08) from TCGA case TCGA-BF-AAP7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 76.9 years (28,073 days).
Specimen TCGA-BF-AAP7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc334b41-ffc7-4b63-bf24-a97cc473934d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAP7-10A (Blood Derived Normal), aliquot TCGA-BF-AAP7-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/258c1dab-af6b-43b4-80f3-4aeccef7283a

The open-access MAF lists 553 somatic variants for this specimen: 366 protein-altering or splice-affecting, 177 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 334, Silent 177, Nonsense Mutation 18, Intron 6, Splice Region 4, Splice Site 4, 5'Flank 3, Frame Shift Del 2, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A1 | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555303010, COSV65432307; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs121913628, CM032609, CM920494, COSV100805670; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1057518425, COSV100909326, COSV64292806; ClinVar: likely pathogenic; called by muse, mutect2
- SMARCA4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60786475, COSV60810612; called by muse, mutect2
- AADACL4 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100879349; called by muse, mutect2, varscan2
- ABCA12 | c.4975G>C p.E1659Q (on ENST00000272895 / NM_173076.3; = p.E1341Q on NM_015657.3) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99788161; called by muse, mutect2, varscan2
- ABCA12 | c.1043C>T p.P348L (on ENST00000272895 / NM_173076.3; = p.P30L on NM_015657.3) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs763523997, COSV99788163; called by muse, mutect2, varscan2
- ABCB8 | c.2005C>T p.R669W (on ENST00000297504 / NM_001282291.2; = p.R652W on NM_007188.5) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754058687, COSV99873726; called by muse, mutect2, varscan2
- AC104452.1 | c.498C>T p.T166= | Splice Region (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99864366; called by muse, mutect2
- ACMSD | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1316716970, COSV99298785; called by muse, mutect2, varscan2
- ACSF3 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1057520194, COSV58082782; called by muse, mutect2, varscan2
- ACSM2B | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs148136861; called by muse, mutect2, varscan2
- ACSS1 | c.1707C>T p.I569= | Splice Region (SNP) | VAF 10/64 reads (16%) | catalogued as rs373928802; called by muse, mutect2, varscan2
- ADAMTS18 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770516167, COSV51399705; called by muse, mutect2, varscan2
- ADAMTS18 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV99271080; called by muse, mutect2, varscan2
- ADGRB3 | c.4128G>T p.L1376F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1469755156, COSV53246334; called by muse, mutect2, varscan2
- ADGRG3 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100342053; called by muse, mutect2, varscan2
- ADGRV1 | c.12793C>T p.P4265S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1172525838, COSV67987740; called by muse, mutect2, varscan2
- ADH1B | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100520635; called by muse, mutect2, varscan2
- AFF2 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV53981943, COSV53983499; called by muse, mutect2, varscan2
- AHCY | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.976); catalogued as COSV99463962; called by muse, mutect2, varscan2
- ALMS1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.958); catalogued as COSV100041054; called by muse, mutect2, varscan2
- AMER1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57656995, COSV57657427; called by muse, mutect2, varscan2
- ANKS1B | c.3499G>A p.D1167N (on ENST00000547776 / NM_152788.4; = p.D333N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100227132; called by muse, mutect2
- AP3B2 | c.2776C>T p.Q926* (on ENST00000261722; = p.Q920* on NM_004644.5) | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV55608270, COSV99916997; called by muse, mutect2, varscan2
- ARHGAP32 | c.1412C>T p.S471L (on ENST00000310343 / NM_001378025.1; = p.S122L on NM_014715.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100086823; called by muse, mutect2, varscan2
- ARHGEF17 | c.3682C>T p.P1228S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.8); catalogued as rs765772237, COSV99734830; called by muse, varscan2
- ARID2 | c.2408G>A p.G803D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100535335; called by muse, mutect2, varscan2
- ARL11 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56292110; called by muse, mutect2, varscan2
- ARPIN | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as rs558274265, COSV100673418; called by muse, mutect2, varscan2
- ASAP1 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100726788; called by muse, mutect2, varscan2
- ASAP3 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369180; called by muse, mutect2, varscan2
- ASPH | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.186); catalogued as COSV100727364; called by muse, mutect2, varscan2
- ASPM | c.3610G>T p.E1204* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99659457, COSV99661090; called by muse, mutect2, varscan2
- ATF1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs371428536; called by muse, mutect2, varscan2
- ATRN | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1176912908; called by muse, mutect2, varscan2
- AURKB | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100298584; called by muse, mutect2, varscan2
- B3GNT2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771301412, COSV100114040; called by muse, mutect2, varscan2
- BAZ2A | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99464653; called by muse, mutect2, varscan2
- BCOR | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100652834; called by muse, mutect2, varscan2
- BLMH | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55585076; called by muse, mutect2, varscan2
- BNIP3 | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV100893143; called by muse, mutect2, varscan2
- BTBD7 | c.2692A>G p.S898G | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.014); catalogued as COSV100597458; called by muse, mutect2, varscan2
- C10orf71 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.203); catalogued as COSV100109674; called by muse, mutect2, varscan2
- C1QC | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1373636175, COSV65889544; called by muse, mutect2, varscan2
- C20orf194 | c.3218A>T p.K1073M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99330239; called by muse, mutect2, varscan2
- C8B | c.239A>C p.Q80P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100980680; called by muse, mutect2, varscan2
- CACNA1A | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as rs371138043, COSV64190861; called by muse, mutect2, varscan2
- CACNA1B | c.1808T>C p.L603P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99495043; called by muse, mutect2, varscan2
- CACNA2D3 | c.2954C>T p.T985I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV99869979; called by muse, mutect2, varscan2
- CAPZA2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as COSV100753817; called by muse, mutect2, varscan2
- CATSPERB | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1329664212, COSV99830774; called by muse, mutect2, varscan2
- CCDC144A | c.3597A>T p.K1199N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100138315; called by mutect2, varscan2
- CCDC40 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1568709715, COSV100884226; called by muse, mutect2, varscan2
- CCDC88B | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766740322, COSV100104972; called by muse, mutect2, varscan2
- CCDC92 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs769392304, COSV99435179; called by muse, mutect2, varscan2
- CCN2 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV100915279; called by muse, mutect2, varscan2
- CCNC | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as rs1270401879, COSV100412528; called by muse, mutect2, varscan2
- CCP110 | c.503T>G p.F168C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV101195213; called by muse, mutect2, varscan2
- CD163L1 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as COSV100549634; called by muse, mutect2, varscan2
- CDH10 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570603, COSV52576617; called by muse, mutect2, varscan2
- CDH10 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100053466, COSV52600363; called by muse, mutect2, varscan2
- CDH17 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99216927; called by muse, mutect2, varscan2
- CENPE | c.6950T>G p.F2317C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99476914; called by muse, mutect2, varscan2
- CFAP44 | c.1711T>A p.F571I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99868843; called by muse, mutect2, varscan2
- CHD6 | c.7775C>T p.P2592L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV100950529; called by muse, mutect2, varscan2
- CHD6 | c.7774C>T p.P2592S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100950530; called by muse, mutect2, varscan2
- CHRM3 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.007); catalogued as COSV99697411; called by muse, mutect2, varscan2
- CHRNA7 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180739; called by mutect2, varscan2
- CIITA | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs371653584; called by muse, mutect2, varscan2
- CLEC4C | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV100665346; called by muse, mutect2, varscan2
- CLNK | c.195T>G p.S65R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99904520; called by muse, mutect2, varscan2
- CMYA5 | c.8545C>T p.H2849Y | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV71404462; called by muse, mutect2, varscan2
- CNOT1 | c.4142C>T p.P1381L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV55318543; called by muse, mutect2, varscan2
- CNOT1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as COSV57780995; called by muse, mutect2, varscan2
- COASY | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs551629036, COSV99888140; called by muse, mutect2, varscan2
- COL15A1 | c.4036G>T p.D1346Y | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs763038024, COSV100897362; called by muse, mutect2, varscan2
- COL4A5 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV60355555; called by muse, mutect2, varscan2
- COL4A6 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563280; called by muse, mutect2, varscan2
- COL6A6 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs752996147, COSV62019642, COSV62023085; called by muse, mutect2, varscan2
- COLEC10 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773102706, COSV100250509; called by muse, mutect2, varscan2
- CR2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs746224290, COSV65509489; called by muse, mutect2, varscan2
- CSMD2 | c.7781C>T p.P2594L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1315871553, COSV99585671; called by muse, mutect2
- CTNNA2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.251); catalogued as rs771474697, COSV100781614; called by muse, mutect2, varscan2
- CYP2C18 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV53669788, COSV99608889; called by muse, mutect2, varscan2
- CYP4X1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV100903276; called by muse, mutect2, varscan2
- DBF4 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1402549274, COSV99719128; called by muse, mutect2, varscan2
- DCAF11 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as COSV100386560; called by muse, mutect2, varscan2
- DCAF11 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV100386562; called by muse, mutect2, varscan2
- DDB1 | c.3062C>T p.S1021F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as COSV100074246, COSV57104776; called by muse, mutect2, varscan2
- DDX27 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1283744604, COSV100872093; called by muse, mutect2, varscan2
- DDX6 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99869956; called by muse, mutect2, varscan2
- DHX15 | c.1115A>G p.E372G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100391118; called by muse, mutect2, varscan2
- DNAH3 | c.5559G>A p.M1853I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99764825; called by muse, mutect2, varscan2
- DNAH8 | c.11100G>A p.M3700I | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV100543171; called by muse, mutect2, varscan2
- DNAJB7 | c.116A>T p.K39I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99343953; called by muse, mutect2, varscan2
- DNHD1 | c.12193G>A p.G4065S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99599392; called by muse, mutect2, varscan2
- DRGX | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as COSV65136513; called by muse, mutect2, varscan2
- DYNC2H1 | c.8015A>T p.H2672L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV100517457; called by muse, mutect2
- EBF1 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100565095; called by muse, mutect2, varscan2
- EML3 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1223751013, COSV99603983; called by muse, mutect2, varscan2
- EPHA2 | c.2118G>A p.E706= | Splice Region (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100626012; called by muse, mutect2, varscan2
- ERBB4 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750966942, COSV99615943; called by muse, mutect2, varscan2
- ERBIN | c.2210T>C p.V737A | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99395790; called by muse, mutect2, varscan2
- ERRFI1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101087953; called by muse, mutect2, varscan2
- EXOC3L2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99374441; called by muse, mutect2
- EXOC3L2 | c.1999-1G>A p.X667_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99374442; called by muse, mutect2
- F11 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99251154; called by muse, mutect2, varscan2
- FAM120AOS | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV99464484; called by muse, mutect2
- FAM3D | c.400A>T p.K134* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100716697; called by muse, mutect2, varscan2
- FAM47B | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV61453998; called by muse, mutect2, varscan2
- FAM71A | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99674349; called by muse, mutect2, varscan2
- FAM71B | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100261748; called by muse, mutect2, varscan2
- FAM71D | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as rs745626593, COSV100315104; called by muse, mutect2, varscan2
- FAM83B | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100173993; called by muse, mutect2, varscan2
- FAM83B | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs756524817, COSV100173994; called by muse, mutect2
- FASN | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100147275; called by muse, mutect2, varscan2
- FAT4 | c.6506C>T p.T2169I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV100627187; called by muse, mutect2, varscan2
- FAT4 | c.7352C>T p.S2451F | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100627188; called by muse, mutect2, varscan2
- FCRL1 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs749728422, COSV100839714; called by muse, mutect2, varscan2
- FLI1 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV55646707, COSV55647773; called by muse, mutect2, varscan2
- FOXA3 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs1394292854, COSV100141210; called by muse, mutect2, varscan2
- FRMPD4 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV66211204; called by muse, mutect2, varscan2
- GAB3 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100850408; called by muse, mutect2
- GABRB3 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV54652613, COSV54668324; called by muse, mutect2, varscan2
- GALNT16 | c.1095G>A p.R365= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as rs753796995, COSV100545697; called by muse, mutect2, varscan2
- GAS7 | c.478G>A p.G160R (on ENST00000432992 / NM_201433.2; = p.G20R on NM_003644.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1455959883, COSV100094410; called by muse, mutect2, varscan2
- GIMAP8 | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100217313; called by muse, mutect2, varscan2
- GPATCH3 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1326761003, COSV100658687; called by muse, mutect2, varscan2
- GPRASP2 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100176548; called by muse, mutect2, varscan2
- GPRC6A | c.1212G>A p.W404* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100113984; called by muse, mutect2, varscan2
- GRIA1 | c.1551G>A p.M517I | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV53624624; called by muse, mutect2, varscan2
- GRIA2 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV99642919; called by muse, mutect2, varscan2
- HASPIN | c.1279A>G p.N427D | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV99560303; called by muse, mutect2, varscan2
- HCCS | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as rs895459281, COSV100335610; called by muse, mutect2, varscan2
- HDAC10 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99298962; called by muse, mutect2, varscan2
- HDAC5 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99870237; called by muse, mutect2
- HDHD5 | c.1025C>T p.A342V (on ENST00000336737 / NM_033070.3; = p.A312V on NM_017829.5) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as rs1271030274, COSV99324450; called by muse, mutect2
- HNRNPH2 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.013); catalogued as COSV100346877; called by muse, mutect2, varscan2
- HOXB1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99495297; called by muse, mutect2
- HTRA3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100246181; called by muse, mutect2, varscan2
- HTRA3 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100246182; called by muse, mutect2, varscan2
- IBSP | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1316015431, COSV56894879; called by muse, mutect2, varscan2
- IFNA13 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV101489462; called by muse, mutect2, varscan2
- IFT172 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753783467, COSV53134395; called by muse, mutect2, varscan2
- IGHV3-66 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.196); catalogued as rs782166609; called by muse, mutect2, varscan2
- INSR | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762687424, COSV57172674; called by muse, mutect2, varscan2
- INSRR | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as COSV100947107; called by muse, mutect2, varscan2
- INTS4 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1401200997, COSV101417120; called by muse, mutect2, varscan2
- INTS6 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV100246872; called by muse, mutect2, varscan2
- IRAG1 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV101350907; called by muse, mutect2, varscan2
- IRF2BP1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100138795; called by muse, mutect2, varscan2
- ITGAE | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs978781357, COSV99560304; called by muse, mutect2, varscan2
- ITGAL | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100776052; called by muse, mutect2, varscan2
- KANK4 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV100443086; called by muse, mutect2, varscan2
- KCNA6 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV54976296; called by muse, mutect2, varscan2
- KCNB2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs866484467, COSV73051743; called by muse, mutect2, varscan2
- KCNQ3 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101195458; called by muse, mutect2, varscan2
- KCTD11 | c.547G>A p.A183T (on ENST00000333751 / NM_001363642.1; = p.A144T on NM_001002914.2) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99341396; called by muse, mutect2, varscan2
- KIAA1217 | c.3959C>T p.S1320F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100286176; called by muse, mutect2, varscan2
- LCK | c.1327+2T>C p.X443_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100287404; called by muse, mutect2, varscan2
- LEFTY2 | c.525G>A p.W175* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100832524; called by muse, mutect2, varscan2
- LIFR | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV99663183; called by muse, mutect2, varscan2
- LRP12 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407108; called by muse, mutect2, varscan2
- LRP2 | c.11206C>T p.R3736C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275575465, COSV55544664; called by muse, mutect2, varscan2
- LRPAP1 | c.955C>A p.R319S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs753917366, COSV99578775; called by muse, mutect2, varscan2
- LTBR | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1274924502, COSV99965170; called by muse, mutect2, varscan2
- LTF | c.1272T>A p.C424* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as rs777999333, COSV99206773; called by muse, mutect2, varscan2
- MACC1 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs200647420, COSV100255326; called by muse, mutect2, varscan2
- MACC1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1374348856, COSV60547429; called by muse, mutect2, varscan2
- MAD2L2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV99335752; called by muse, mutect2, varscan2
- MAGEB18 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100305281; called by muse, mutect2, varscan2
- MAGEE1 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV100819253; called by muse, mutect2, varscan2
- MAP2 | c.4787C>T p.P1596L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557687; called by muse, mutect2, varscan2
- MAPK4 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs752849769, COSV101245079; called by muse, mutect2, varscan2
- MAPKBP1 | c.3541C>T p.P1181S (on ENST00000456763 / NM_001128608.2; = p.P1175S on NM_014994.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99528887; called by muse, mutect2, varscan2
- MARVELD2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs142099889; called by muse, mutect2, varscan2
- MEIS2 | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); catalogued as COSV99575711; called by muse, mutect2, varscan2
- MTBP | c.1083T>G p.S361R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100011804; called by muse, mutect2, varscan2
- MTMR3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs1209162116, COSV100070442; called by muse, mutect2, varscan2
- MUC16 | c.31569G>A p.M10523I | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs763795565, COSV101198050; called by muse, mutect2, varscan2
- MUC16 | c.15878C>T p.S5293F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV67470033; called by muse, mutect2, varscan2
- MUC16 | c.7412C>T p.P2471L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV101198052; called by muse, mutect2, varscan2
- MUC17 | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 81/370 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100071500, COSV60281838; called by muse, mutect2, varscan2
- MYCT1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100924023; called by muse, mutect2
- MYH4 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV55114596; called by muse, mutect2, varscan2
- MYO18B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs777220977, COSV100122527; called by muse, mutect2
- MYO9B | c.2747T>G p.V916G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV101261236; called by muse, mutect2
- NAAA | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV99715736; called by muse, mutect2, varscan2
- NAPRT | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99434265; called by muse, mutect2, varscan2
- NDUFAF5 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99176252; called by muse, mutect2, varscan2
- NFATC2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101043561, COSV101043788; called by muse, mutect2, varscan2
- NFKBIL1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.59); catalogued as COSV100385332; called by muse, mutect2, varscan2
- NLRP13 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV61620393; called by muse, mutect2, varscan2
- NLRP3 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865858890, COSV100275213; called by muse, mutect2, varscan2
- NLRP3 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60219497; called by muse, mutect2, varscan2
- NPAS3 | c.506G>A p.G169E (on ENST00000356141 / NM_001164749.2; = p.G137E on NM_022123.3) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58072942; called by muse, mutect2, varscan2
- NPHS1 | c.3460G>T p.E1154* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100799583, COSV100800321; called by muse, mutect2, varscan2
- NUP85 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as COSV99821875; called by mutect2, varscan2
- OAZ3 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100162307; called by muse, mutect2, varscan2
- OPN5 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.289); catalogued as COSV55247464, COSV99789700; called by muse, mutect2, varscan2
- OR10W1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101223602; called by muse, mutect2, varscan2
- OR14A16 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as rs1214260748, COSV100713690, COSV62926569; called by muse, mutect2, varscan2
- OR2A5 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs901417430, COSV101278663, COSV68738525; called by muse, mutect2, varscan2
- OR2L8 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100594018; called by muse, mutect2, varscan2
- OR4K14 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100520328; called by muse, mutect2, varscan2
- OR4K2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1288967692, COSV53849761; called by muse, mutect2, varscan2
- OR4K5 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262079, COSV100262124; called by muse, mutect2, varscan2
- OSBPL6 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs868428618, COSV99506468; called by muse, mutect2, varscan2
- PAMR1 | c.998G>A p.G333E (on ENST00000619888 / NM_001001991.3; = p.G350E on NM_015430.4) | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1279935811, COSV99552091; called by muse, mutect2, varscan2
- PASD1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.062); catalogued as COSV64855543; called by muse, mutect2, varscan2
- PAXBP1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99268990; called by muse, mutect2, varscan2
- PBDC1 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100972775; called by muse, mutect2, varscan2
- PCDH9 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1183041683, COSV100118193, COSV60559484; called by muse, mutect2, varscan2
- PCDHGA3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV53902853, COSV54066637; called by muse, mutect2, varscan2
- PCDHGA4 | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99530085; called by muse, mutect2, varscan2
- PCLO | c.4715C>T p.S1572F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427142; called by muse, mutect2, varscan2
- PCSK7 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199538186, COSV100309165, COSV100309547; called by muse, mutect2, varscan2
- PCYT1A | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99491917; called by muse, mutect2, varscan2
- PDZRN3 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs373980887, COSV99732843; called by muse, varscan2
- PER3 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as rs370974877, COSV62704919; called by muse, mutect2, varscan2
- PGLYRP2 | c.955C>G p.R319G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52992406, COSV99483752; called by muse, mutect2, varscan2
- PIK3CB | c.631A>G p.S211G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as rs773791563, COSV56687681; called by muse, mutect2, varscan2
- PKD1L1 | c.6674G>A p.W2225* | Nonsense Mutation (SNP) | VAF 39/151 reads (26%) | catalogued as COSV99218300; called by muse, mutect2, varscan2
- PKP2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV50739019; called by muse, mutect2, varscan2
- PLCG2 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV63868230; called by muse, mutect2, varscan2
- PLD1 | c.2816C>T p.S939L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100577571; called by muse, mutect2, varscan2
- PLEKHF2 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100193317; called by muse, mutect2, varscan2
- PLEKHF2 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100193319; called by muse, mutect2, varscan2
- PRAC1 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV99284785; called by muse, mutect2, varscan2
- PRDM13 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100980432; called by muse, mutect2, varscan2
- PREX2 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779079528, COSV55753944; called by muse, mutect2, varscan2
- PRKAB1 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99982213; called by muse, mutect2, varscan2
- PRKDC | c.8422C>T p.L2808F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100038276; called by muse, mutect2, varscan2
- PROKR1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.124); catalogued as rs1257273361, COSV100375248; called by muse, mutect2, varscan2
- PRSS1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61192366; called by muse, mutect2, varscan2
- PRTG | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs201047603; called by muse, mutect2, varscan2
- PRUNE2 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.306); catalogued as rs1286143216, COSV100944198; called by muse, mutect2, varscan2
- PRX | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.406); catalogued as COSV99397417; called by muse, mutect2, varscan2
- PSG4 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99066890, COSV99736167; called by muse, mutect2, varscan2
- PSG4 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1207584209, COSV99736172; called by muse, mutect2, varscan2
- PSG6 | c.1027T>C p.Y343H | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.838); catalogued as COSV99413510; called by muse, mutect2, varscan2
- PSG9 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1266526283, COSV99392023; called by muse, mutect2, varscan2
- PTK7 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.472); catalogued as rs748567987, COSV57848765; called by muse, mutect2, varscan2
- QRICH2 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV99428768; called by muse, mutect2, varscan2
- RAB32 | c.354A>T p.L118F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV62249290; called by muse, mutect2, varscan2
- RBM47 | c.1225A>T p.S409C | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV99920091; called by muse, mutect2, varscan2
- RC3H1 | c.2393T>C p.V798A | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99281004; called by muse, mutect2
- RETREG2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.262); catalogued as COSV99811352; called by muse, mutect2, varscan2
- RETSAT | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs867570807, COSV99805830; called by muse, mutect2, varscan2
- RGR | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100812850; called by muse, mutect2
- RHAG | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1344188537, COSV100006281; called by muse, mutect2, varscan2
- RIMS4 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs764069520, COSV100865058; called by muse, mutect2, varscan2
- RLF | c.2843G>T p.C948F | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV101035064; called by muse, mutect2, varscan2
- RNF43 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV68457329; called by muse, mutect2, varscan2
- RPE | c.361C>T p.P121S (on ENST00000359429 / NM_001318926.1; = p.P71S on NM_006916.2) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99910122; called by muse, mutect2, varscan2
- RPE | c.362C>T p.P121L (on ENST00000359429 / NM_001318926.1; = p.P71L on NM_006916.2) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99910123; called by muse, mutect2, varscan2
- RPL5 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV100240250; called by muse, mutect2, varscan2
- RTTN | c.5763A>T p.K1921N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99730944; called by muse, mutect2, varscan2
- RUNX2 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV100767103; called by muse, mutect2, varscan2
- RYR2 | c.12452A>G p.E4151G | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100767638; called by muse, mutect2, varscan2
- S100Z | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV100460929; called by muse, mutect2, varscan2
- SBNO1 | c.2608C>T p.P870S (on ENST00000420886; = p.P869S on NM_018183.5) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99928668; called by muse, mutect2, varscan2
- SCML2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52622521; called by muse, mutect2, varscan2
- SCN1A | c.2743A>C p.S915R (on ENST00000303395 / NM_001202435.3; = p.S904R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as CD065788, COSV100319188; called by muse, mutect2, varscan2
- SCTR | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.135); catalogued as rs1449006651, COSV99191496; called by muse, mutect2, varscan2
- SECISBP2L | c.2378G>A p.G793E (on ENST00000559471 / NM_001193489.2; = p.G748E on NM_014701.4) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99959821; called by muse, mutect2, varscan2
- SEMA3E | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100317200; called by muse, mutect2, varscan2
- SEMA5B | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV99530755; called by muse, mutect2, varscan2
- SEPHS1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV59258680; called by muse, mutect2, varscan2
- SERPINB3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52193036; called by muse, mutect2, varscan2
- SETD1A | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99352378; called by muse, mutect2, varscan2
- SEZ6 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1390893937, COSV100252637; called by muse, mutect2, varscan2
- SGK1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV99397685; called by muse, mutect2, varscan2
- SIK3 | c.3302C>T p.P1101L (on ENST00000445177 / NM_001366686.2; = p.P1059L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99407187; called by muse, mutect2, varscan2
- SIRPB1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99498154; called by muse, mutect2, varscan2
- SIRT1 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as rs770824011, COSV99281581; called by muse, mutect2, varscan2
- SIRT1 | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV99281582; called by muse, mutect2, varscan2
- SKA3 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100006084; called by muse, mutect2, varscan2
- SLC16A14 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV99725150; called by muse, mutect2, varscan2
- SLC22A16 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs747426690, COSV100397118; called by muse, mutect2, varscan2
- SLC36A1 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV54652223; called by muse, mutect2, varscan2
- SLC38A2 | c.1055-2A>G p.X352_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99873708; called by muse, mutect2, varscan2
- SLC8A3 | c.2090C>T p.S697F (on ENST00000381269 / NM_183002.3; = p.S695F on NM_033262.4) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53691526; called by muse, mutect2, varscan2
- SLC9A2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV99295819; called by muse, mutect2, varscan2
- SLC9A6 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV100857834; called by muse, mutect2, varscan2
- SLF1 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54367165; called by muse, mutect2, varscan2
- SLITRK4 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs868983945, COSV62022882; called by muse, varscan2
- SLX4 | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV99567575; called by muse, varscan2
- SLX4IP | c.56T>A p.L19H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100570147; called by muse, mutect2
- SORCS2 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100211391; called by muse, mutect2
- SOX7 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100448956; called by muse, mutect2, varscan2
- SPEF2 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV61551721; called by muse, mutect2, varscan2
- SPEN | c.1689A>T p.E563D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.279); catalogued as COSV101004991; called by muse, mutect2, varscan2
- SPTBN2 | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.088); catalogued as rs1157975435, COSV100018112; called by muse, mutect2
- STK19 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV61712750; called by muse, mutect2, varscan2
- STK31 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV63454655; called by muse, mutect2, varscan2
- STON2 | c.1109A>G p.N370S (on ENST00000649389 / NM_001366849.2; = p.N313S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as rs757222803, COSV99964371; called by muse, mutect2, varscan2
- STYXL2 | c.3181A>G p.N1061D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1031230930, COSV99608545; called by muse, mutect2, varscan2
- SWT1 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100833036; called by muse, mutect2
- SYN1 | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99927054; called by muse, mutect2
- SYNE1 | c.20779G>A p.E6927K (on ENST00000367255 / NM_182961.4; = p.E6856K on NM_033071.3) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399115677, COSV99552371; called by muse, mutect2, varscan2
- TACC2 | c.7052C>T p.S2351F (on ENST00000334433; = p.S429F on NM_006997.4) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99586551; called by muse, mutect2, varscan2
- TCTEX1D2 | c.428G>T p.*143Lext*4 | Nonstop Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99491918; called by muse, mutect2, varscan2
- TENM4 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1353758778, COSV99570636; called by muse, mutect2, varscan2
- TET2 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs201433011, COSV54408518, COSV54425739, COSV99480737; called by muse, mutect2, varscan2
- THSD7B | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.425); catalogued as rs1375683866, COSV55727191; called by muse, mutect2, varscan2
- TMEM130 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs1479985765, COSV100228527; called by mutect2, varscan2
- TMEM41A | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV99406360; called by muse, mutect2, varscan2
- TNIP2 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100198578; called by muse, mutect2, varscan2
- TNIP2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1186135723, COSV100198579; called by muse, mutect2, varscan2
- TNRC6B | c.2383G>A p.G795S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.033); catalogued as COSV100108920; called by muse, mutect2, varscan2
- TNXB | c.6691C>T p.P2231S (on ENST00000647633; = p.P1984S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as rs757950715, COSV100925771; called by muse, mutect2, varscan2
- TPTE | c.871G>A p.D291N (on ENST00000618007 / NM_199261.4; = p.D273N on NM_199259.4) | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.493); catalogued as rs373367615; called by muse, mutect2
- TRIM60 | c.309T>G p.F103L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100593911; called by muse, mutect2, varscan2
- TRIOBP | c.6307C>G p.P2103A (on ENST00000644935 / NM_001039141.3; = p.P390A on NM_007032.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV100462214; called by muse, mutect2
- TRPC6 | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100723446; called by muse, varscan2
- TRPM5 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99329492; called by muse, mutect2
- TRRAP | c.7712C>T p.T2571I (on ENST00000359863 / NM_001244580.1; = p.T2553I on NM_003496.3) | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100721941; called by muse, mutect2, varscan2
- TSHZ2 | c.2927C>T p.S976L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs373149702, COSV100295584; called by muse, mutect2, varscan2
- TTN | c.77596G>A p.E25866K (on ENST00000591111; = p.E18442K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | PolyPhen possibly damaging (0.475); catalogued as COSV100593225, COSV60042925; called by muse, mutect2, varscan2
- TULP2 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs966161211, COSV55479341; called by muse, mutect2, varscan2
- UNC5A | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.74); catalogued as COSV99994146; called by muse, mutect2, varscan2
- UNC5C | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1430145819, COSV101497774; called by muse, mutect2, varscan2
- USP12 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99997390; called by muse, mutect2, varscan2
- USP19 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs778762747, COSV100025787; called by muse, mutect2
- USP29 | c.562A>C p.N188H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV99517614; called by muse, mutect2, varscan2
- USP7 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100783963; called by muse, mutect2, varscan2
- USPL1 | c.3128C>A p.T1043K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV99687000; called by muse, mutect2, varscan2
- UVRAG | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100638103; called by mutect2, varscan2
- VARS1 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.196); catalogued as COSV100989531; called by muse, mutect2, varscan2
- VAT1L | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV100212925; called by muse, mutect2, varscan2
- VPS13A | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs773985427, COSV62439124; called by muse, mutect2, varscan2
- WDR33 | c.3280C>T p.P1094S | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.011); catalogued as rs201256336, COSV100459517; called by muse, mutect2, varscan2
- WFDC8 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1568992836, COSV51488871; called by muse, mutect2, varscan2
- XK | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101064516; called by muse, mutect2, varscan2
- ZAN | c.5005C>T p.P1669S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs750040768, COSV100769094; called by muse, mutect2, varscan2
- ZC3H13 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.732); catalogued as rs267603832, COSV99667413; called by muse, mutect2, varscan2
- ZDBF2 | c.4483G>A p.D1495N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100984328; called by muse, mutect2, varscan2
- ZNF121 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV100248075; called by muse, mutect2, varscan2
- ZNF385A | c.733G>A p.G245R (on ENST00000338010 / NM_001130967.3; = p.G225R on NM_015481.3) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100566757; called by muse, mutect2, varscan2
- ZNF385D | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1305245934, COSV55764730; called by muse, varscan2
- ZNF446 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as rs1298454692, COSV99543095; called by muse, mutect2, varscan2
- ZNF446 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1050307707, COSV99543097; called by muse, mutect2, varscan2
- ZNF491 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs746354618, COSV60058991; called by muse, mutect2, varscan2
- ZNF565 | c.701C>T p.P234L (on ENST00000355114; = p.P194L on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100411739; called by muse, mutect2
- ZNF566 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.635); catalogued as COSV101091223; called by muse, mutect2, varscan2
- ZNF624 | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV100256987; called by muse, mutect2, varscan2
- ZNF711 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99340620; called by muse, mutect2, varscan2
- ZNF766 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100765253; called by muse, mutect2, varscan2
- ZNF98 | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63335931; called by muse, mutect2, varscan2
- ZPBP | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99248992; called by muse, mutect2
- ZSWIM5 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as COSV100655318, COSV62733831; called by muse, mutect2, varscan2
- ZSWIM8 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101289785; called by muse, mutect2, varscan2
- ZXDC | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs751544844, COSV100306291; called by muse, mutect2, varscan2
- ARID2 | c.5250_5253delinsG p.N1750_L1751delinsK | In Frame Del (DEL) | VAF 20/89 reads (22%) | called by pindel, varscan2*
- ATRN | c.3556C>T p.P1186S | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CDKN2A | c.372_374delinsGG p.D125Vfs*21 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by pindel, varscan2*
- CHD7 | c.8272C>T p.L2758F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- FBXO11 | c.1491_1497del p.I497Mfs*18 (on ENST00000403359 / NM_001190274.2; = p.I413Mfs*18 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- IGHA1 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGKV1-17 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- LIX1L | c.277dup p.Q93Pfs*25 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- NBPF7 | n.605+1G>A | Splice Site (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2
- TRBV30 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ABCB8 | c.2004C>T p.H668= (on ENST00000297504 / NM_001282291.2; = p.H651= on NM_007188.5) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1337365405, COSV99873721; called by muse, mutect2, varscan2
- ACHE | c.1164C>T p.A388= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs755962641, COSV53823046; called by muse, varscan2
- ACSL4 | c.1195C>T p.L399= (on ENST00000340800 / NM_022977.2; = p.L358= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100538260; called by muse, mutect2, varscan2
- ACSM1 | c.987C>T p.F329= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs746038493, COSV54633872; called by muse, mutect2, varscan2
- ACTL9 | c.354C>T p.I118= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs782337387, COSV100185101; called by muse, mutect2
- ADAM29 | c.1344C>T p.F448= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs768870601, COSV63660502; called by muse, mutect2, varscan2
- ADAMTS12 | c.2328G>A p.R776= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100710243; called by muse, mutect2, varscan2
- ADD2 | c.1917C>G p.P639= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs1553365538, COSV100034597, COSV52459154; called by muse, mutect2, varscan2
- ADGRB2 | c.3291C>T p.I1097= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs367578737; called by muse, mutect2, varscan2
- AFF2 | c.1590G>A p.L530= | Silent (SNP) | VAF 25/207 reads (12%) | catalogued as COSV99661757; called by muse, mutect2, varscan2
- AGER | c.246C>T p.G82= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100904940; called by muse, mutect2, varscan2
- AGRN | c.5625C>T p.V1875= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs780605830, COSV101038571; called by muse, mutect2, varscan2
- AHCTF1 | c.1383T>C p.S461= (on ENST00000366508; = p.S435= on NM_015446.5) | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as COSV100403078; called by muse, mutect2, varscan2
- ALS2 | c.1476C>T p.S492= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1227189108, COSV51891014; called by muse, mutect2, varscan2
- ANKRD10 | c.540C>T p.L180= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99941022; called by muse, mutect2, varscan2
- ASCC2 | c.885G>A p.K295= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100315954; called by muse, mutect2, varscan2
- ASCC3 | c.36C>T p.S12= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100225170; called by muse, mutect2, varscan2
- ASIC5 | c.1206G>A p.K402= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV101611096, COSV73332996; called by muse, mutect2, varscan2
- ASTN1 | c.1224C>T p.L408= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs929049750, COSV99920373; called by muse, mutect2, varscan2
- AXIN1 | c.633G>A p.T211= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs779687565, COSV51988210; called by muse, mutect2, varscan2
- B3GNT2 | c.483C>T p.I161= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100114037; called by muse, mutect2, varscan2
- BABAM1 | c.681C>T p.S227= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV63919969; called by muse, mutect2
- BCL6B | c.1125C>T p.S375= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV53427422; called by muse, mutect2, varscan2
- C12orf40 | c.1476C>T p.F492= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100209612; called by muse, mutect2, varscan2
- C2orf16 | c.1332G>A p.R444= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV101284329; called by muse, mutect2, varscan2
- CABIN1 | c.3216C>T p.S1072= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs774332584, COSV99572653; called by muse, mutect2, varscan2
- CCDC88C | c.4395C>T p.S1465= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100484653; called by muse, mutect2, varscan2
- CCDC92 | c.834C>T p.S278= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1256738573, COSV99435181; called by muse, mutect2, varscan2
- CCND1 | c.594T>C p.N198= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99919194; called by muse, mutect2, varscan2
- CDH16 | c.1746C>T p.F582= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs142024712; called by muse, mutect2, varscan2
- CHD1 | c.4551G>A p.L1517= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99399068; called by muse, mutect2, varscan2
- CHD7 | c.8271C>T p.S2757= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- CHRDL2 | c.726C>T p.I242= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs754375233, COSV55221565; called by muse, mutect2, varscan2
- CHRNE | c.843C>T p.L281= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1221054751, COSV99544526; called by muse, mutect2, varscan2
- CLU | c.858G>A p.R286= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1328403339, COSV100324120; called by muse, mutect2, varscan2
- CMYA5 | c.4344T>C p.L1448= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV101483808; called by muse, mutect2, varscan2
- CNTN1 | c.3036C>T p.I1012= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100750923; called by muse, mutect2, varscan2
- COL6A5 | c.6609G>A p.L2203= (on ENST00000312481; = p.L2199= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99591845; called by muse, mutect2, varscan2
- CSMD1 | c.9516C>T p.F3172= (on ENST00000520002; = p.F3171= on NM_033225.6) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV59276442; called by muse, mutect2, varscan2
- CSMD1 | c.6801G>A p.Q2267= (on ENST00000520002; = p.Q2266= on NM_033225.6) | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs755840902, COSV100143274, COSV59344331; called by muse, mutect2, varscan2
- CTNND2 | c.2628G>A p.G876= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100471378; called by muse, mutect2, varscan2
- DDX39A | c.489C>T p.N163= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV99660126; called by muse, mutect2, varscan2
- DEFB131A | c.159C>T p.F53= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100607802; called by muse, mutect2, varscan2
- DGKB | c.807G>A p.G269= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99336202; called by muse, mutect2, varscan2
- DMXL2 | c.5661C>T p.T1887= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV99195941; called by muse, mutect2, varscan2
- DNAH11 | c.1056G>A p.T352= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs745357120, COSV100176896; called by muse, mutect2, varscan2
- DNAH17 | c.9705C>T p.S3235= | Silent (SNP) | VAF 59/229 reads (26%) | catalogued as COSV101101362; called by muse, mutect2, varscan2
- DNAH2 | c.1110C>T p.I370= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99317871; called by muse, mutect2, varscan2
- DNAJC7 | c.234C>T p.F78= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100347458; called by muse, mutect2, varscan2
- DRD5 | c.1032C>T p.F344= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV58578101; called by muse, mutect2, varscan2
- DSCAML1 | c.3436C>T p.L1146= (on ENST00000321322; = p.L1086= on NM_020693.4) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100354486; called by muse, mutect2, varscan2
- DSP | c.183G>A p.T61= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs150383703; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFHC2 | c.960C>T p.F320= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs372092672, COSV69554555; called by muse, mutect2, varscan2
- EHBP1 | c.3045T>G p.T1015= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99859951; called by muse, mutect2, varscan2
- EML3 | c.1941C>T p.H647= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99603985; called by muse, mutect2, varscan2
- EMP2 | c.342C>T p.S114= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1333601363, COSV100852766; called by muse, mutect2, varscan2
- EPS8L2 | c.1089C>T p.I363= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs747102402, COSV100585287; called by muse, mutect2, varscan2
- ERC2 | c.2241C>T p.I747= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs750905847, COSV55614799; called by muse, mutect2, varscan2
- FADS3 | c.1032C>T p.I344= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs776413719, COSV99605091; called by muse, mutect2, varscan2
- FAM187B | c.96G>A p.Q32= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100219950; called by muse, mutect2, varscan2
- FARP2 | c.2547C>T p.S849= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs144335206; called by muse, mutect2, varscan2
- FASN | c.2088G>A p.Q696= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs372743066; called by muse, mutect2, varscan2
- FCER2 | c.510C>T p.F170= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100689484; called by muse, mutect2, varscan2
- FCRLB | c.192C>T p.G64= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100396075; called by muse, mutect2, varscan2
- FRMPD4 | c.3387G>A p.K1129= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV101042086; called by muse, mutect2, varscan2
- FSIP2 | c.17514G>A p.E5838= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100553905, COSV100554592, COSV100556893; called by muse, mutect2, varscan2
- GABRB3 | c.1362C>T p.I454= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs745449592, COSV100162335, COSV54657356; called by muse, mutect2, varscan2
- GPC5 | c.582C>T p.I194= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV100992753; called by muse, mutect2, varscan2
- HDHD5 | c.1026C>T p.A342= (on ENST00000336737 / NM_033070.3; = p.A312= on NM_017829.5) | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs149209397; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.15G>A p.A5= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs752236617, COSV100676455; called by muse, mutect2, varscan2
- IGSF1 | c.2877C>T p.P959= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV100811801; called by muse, mutect2, varscan2
- IL22RA1 | c.249G>A p.V83= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99582760; called by muse, mutect2, varscan2
- IP6K2 | c.1032C>T p.V344= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99583674; called by muse, mutect2, varscan2
- IQCE | c.1857C>T p.A619= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1179712048, COSV100383164; called by muse, mutect2, varscan2
- IRAG2 | c.3096G>A p.T1032= (on ENST00000636465; = p.T77= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs565921441, COSV63138195; called by muse, mutect2, varscan2
- ITGAE | c.538C>T p.L180= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as COSV99560306; called by muse, mutect2, varscan2
- ITGB1BP1 | c.409T>C p.L137= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99431767; called by muse, mutect2, varscan2
- JCAD | c.273G>A p.S91= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs368195303; called by muse, mutect2, varscan2
- KCNK13 | c.756G>A p.E252= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV56411606, COSV99965487; called by muse, mutect2, varscan2
- KDM5A | c.3630C>T p.F1210= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV101238596; called by muse, mutect2, varscan2
- KIF13A | c.5331C>T p.L1777= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99433647; called by muse, mutect2, varscan2
- KIF17 | c.1671G>A p.E557= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99928476; called by muse, mutect2, varscan2
- KIFC1 | c.1077C>T p.T359= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs1441146848, COSV100997075; called by muse, mutect2, varscan2
- KRT77 | c.897G>A p.L299= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100526907; called by muse, mutect2, varscan2
- LAG3 | c.846C>T p.C282= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99179877; called by muse, mutect2, varscan2
- LGR6 | c.1383C>T p.S461= (on ENST00000367278 / NM_001017403.1; = p.S409= on NM_021636.3) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1234713792, COSV99705971; called by muse, mutect2, varscan2
- LILRB2 | c.12C>T p.I4= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs764658904, COSV58745511; called by muse, mutect2, varscan2
- LILRB3 | c.486G>A p.Q162= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- LRRC32 | c.423G>A p.L141= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99476647; called by muse, mutect2, varscan2
- LTBP1 | c.3120C>T p.D1040= (on ENST00000404816 / NM_206943.4; = p.D714= on NM_000627.4) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs868717776, COSV99697697; called by mutect2, varscan2
- MAN1C1 | c.1330C>T p.L444= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99847741; called by muse, mutect2
- MAOB | c.1254G>A p.V418= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100955891; called by muse, mutect2, varscan2
- MAP2K3 | c.480A>T p.T160= (on ENST00000342679 / NM_145109.3; = p.T131= on NM_002756.4) | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- MAPK15 | c.177G>A p.R59= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs1185506542, COSV62028879; called by muse, mutect2, varscan2
- MDGA2 | c.1353T>C p.S451= (on ENST00000399232 / NM_001113498.2; = p.S153= on NM_182830.4) | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV100636307; called by muse, mutect2, varscan2
- MEF2B | c.609G>A p.P203= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs754747196, COSV99364273; called by muse, mutect2, varscan2
- MSR1 | c.240G>A p.T80= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs749203568, COSV50521510; called by muse, mutect2, varscan2
- MUC16 | c.7563G>A p.K2521= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV101198051, COSV101200497; called by muse, mutect2, varscan2
- MUC3A | c.7695C>T p.S2565= | Silent (SNP) | VAF 43/344 reads (13%) | catalogued as COSV60210622; called by muse, mutect2, varscan2
- MXRA5 | c.7146C>T p.S2382= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV99475629; called by muse, mutect2, varscan2
- MYH9 | c.3213C>T p.I1071= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs552133535, COSV53390864; ClinVar: uncertain significance; called by muse, mutect2
- MYO18A | c.3921C>T p.S1307= | Silent (SNP) | VAF 51/272 reads (19%) | catalogued as rs375795409; called by muse, mutect2, varscan2
- MYO3A | c.3297G>A p.R1099= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV56321290; called by muse, mutect2, varscan2
- NLRP2 | c.1444C>T p.L482= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99671851; called by muse, mutect2, varscan2
- NOX5 | c.1134C>T p.L378= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs1227813483, COSV99533231; called by muse, mutect2
- OR10G7 | c.846C>T p.F282= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs1369986452, COSV57866568; called by muse, mutect2, varscan2
- OR11L1 | c.492C>T p.S164= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs750973577, COSV100869379; called by muse, mutect2
- OR1G1 | c.39C>T p.F13= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV61030835; called by muse, mutect2
- OR6Q1 | c.462G>A p.L154= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV56932970; called by muse, mutect2, varscan2
- OR6Y1 | c.108C>T p.F36= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs775578919, COSV56928746; called by muse, mutect2, varscan2
- OR8S1 | c.657C>T p.T219= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100043445; called by muse, mutect2, varscan2
- P2RX5 | c.837C>T p.S279= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99835618; called by muse, mutect2, varscan2
- PABPC3 | c.1338T>C p.S446= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV99878962; called by muse, varscan2
- PAPLN | c.1044G>A p.R348= (on ENST00000554301; = p.R321= on NM_173462.4) | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs1378995481, COSV99388992; called by muse, mutect2, varscan2
- PASK | c.2685C>T p.S895= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs761326448, COSV99298600; called by muse, mutect2, varscan2
- PBDC1 | c.393G>A p.E131= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100972774; called by muse, mutect2, varscan2
- PCDHB10 | c.2239C>T p.L747= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV99503607; called by muse, mutect2, varscan2
- PCDHGC4 | c.1326C>T p.F442= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99337817; called by muse, mutect2, varscan2
- PFAS | c.312C>T p.I104= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs762239574, COSV58979049; called by muse, mutect2, varscan2
- PGAP4 | c.696C>T p.F232= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV66387234; called by muse, mutect2, varscan2
- PIGO | c.1257G>T p.A419= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99956392; called by muse, mutect2, varscan2
- PLCB4 | c.582A>G p.G194= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as rs1186199977, COSV99594232; called by muse, mutect2, varscan2
- PLCG2 | c.27C>T p.S9= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs772778136, COSV63870965; called by muse, mutect2, varscan2
- PLS1 | c.1782C>T p.I594= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs376466830, COSV100537943; called by muse, mutect2, varscan2
- PPP4R4 | c.2121G>A p.L707= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100428248; called by muse, mutect2
- PPP5C | c.738G>A p.Q246= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99180830; called by muse, mutect2, varscan2
- PRAG1 | c.3948C>T p.I1316= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100421819; called by muse, mutect2, varscan2
- PREX2 | c.483C>A p.P161= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV55773623, COSV55805610; called by muse, mutect2, varscan2
- PRX | c.1377C>T p.A459= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV99397418; called by muse, mutect2, varscan2
- PSD2 | c.1467G>A p.T489= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs374414299; called by muse, mutect2, varscan2
- PTPN7 | c.921C>T p.G307= (on ENST00000495688; = p.G346= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100459627; called by muse, mutect2
- PXDNL | c.2184C>T p.R728= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs746553805, COSV62480672; called by muse, mutect2, varscan2
- RFX5 | c.879C>T p.A293= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100923817; called by muse, mutect2, varscan2
- RYR1 | c.5157C>T p.L1719= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs772867465, COSV100614339; called by muse, mutect2, varscan2
- SALL4 | c.1614G>A p.G538= | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as COSV99409136; called by muse, mutect2, varscan2
- SAMD7 | c.12C>T p.N4= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100156733; called by muse, mutect2, varscan2
- SEMA4G | c.1503C>T p.I501= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs1453643880, COSV99271878; called by muse, mutect2, varscan2
- SETD1A | c.1188T>A p.P396= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as COSV52688105, COSV99352375; called by muse, mutect2, varscan2
- SFXN5 | c.691C>T p.L231= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1238042085, COSV99728813; called by muse, mutect2
- SKA3 | c.1026A>G p.T342= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100006088; called by muse, mutect2, varscan2
- SLC17A6 | c.21G>A p.R7= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs757004482, COSV99580659; called by muse, mutect2, varscan2
- SLC22A7 | c.1146C>T p.F382= (on ENST00000372585 / NM_153320.2; = p.F380= on NM_006672.3) | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs752067724, COSV99240082; called by muse, mutect2, varscan2
- SLC25A11 | c.471G>A p.Q157= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99337221; called by muse, mutect2, varscan2
- SLC43A1 | c.1077C>T p.F359= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs138052685; called by muse, mutect2, varscan2
- SLC7A14 | c.288C>T p.V96= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99200341; called by muse, mutect2, varscan2
- SLC7A9 | c.1410C>T p.T470= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99195185; called by muse, mutect2, varscan2
- SLC9A5 | c.222C>T p.V74= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV99263802; called by muse, mutect2, varscan2
- SLCO6A1 | c.672C>T p.F224= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV101134878, COSV65809909; called by muse, mutect2, varscan2
- SLX4 | c.2025G>A p.G675= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99567572; called by muse, varscan2
- SON | c.2416T>C p.L806= | Silent (SNP) | VAF 40/240 reads (17%) | catalogued as COSV99276741; called by muse, varscan2
- SPEF2 | c.3372G>A p.K1124= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV100606223; called by muse, mutect2, varscan2
- STAB2 | c.942C>T p.F314= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs144975292, COSV66337677; called by muse, mutect2, varscan2
- STARD3 | c.1167C>T p.I389= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs753831085, COSV59224562; called by muse, mutect2, varscan2
- SVOPL | c.699G>A p.G233= (on ENST00000419765; = p.G81= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV99939028; called by muse, mutect2, varscan2
- TDRD10 | c.51G>A p.K17= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100872960; called by muse, mutect2, varscan2
- TEKT1 | c.1140G>A p.E380= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100105901; called by muse, mutect2, varscan2
- TEX45 | c.135G>A p.R45= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1469546782, COSV100861785; called by muse, mutect2, varscan2
- TMEM94 | c.2838C>T p.S946= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs144804472; called by muse, mutect2, varscan2
- TMPRSS9 | c.936C>T p.I312= (on ENST00000648592; = p.I278= on NM_182973.2) | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1015038038, COSV60231350; called by muse, mutect2, varscan2
- TNFRSF17 | c.258G>A p.K86= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99273113; called by muse, mutect2, varscan2
- TNIP2 | c.942G>A p.R314= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100198576; called by muse, mutect2, varscan2
- TPD52L3 | c.336G>A p.V112= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV58828685; called by muse, mutect2, varscan2
- TRIP10 | c.1602C>T p.F534= (on ENST00000313244 / NM_001288962.2; = p.F478= on NM_004240.4) | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs375875671; called by muse, mutect2, varscan2
- TSC2 | c.4212G>A p.K1404= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99237099; called by muse, mutect2, varscan2
- UAP1 | c.852C>T p.N284= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs756365740, COSV99617365; called by muse, mutect2, varscan2
- UGT1A6 | c.99T>G p.P33= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100529447; called by muse, mutect2, varscan2
- ULK1 | c.2517G>A p.E839= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100416478, COSV58855057; called by muse, mutect2
- VWA3A | c.612G>A p.K204= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101233041; called by muse, mutect2
- VWC2L | c.150G>A p.G50= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100435221; called by muse, mutect2, varscan2
- WAPL | c.2154C>T p.L718= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99556261; called by muse, mutect2, varscan2
- WDR81 | c.5385C>T p.S1795= (on ENST00000409644 / NM_001163809.2; = p.S744= on NM_152348.4) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs779039593, COSV100488495; called by muse, mutect2, varscan2
- XKR7 | c.996C>T p.I332= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV73812910; called by muse, mutect2, varscan2
- ZNF385A | c.732G>A p.L244= (on ENST00000338010 / NM_001130967.3; = p.L224= on NM_015481.3) | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV100566758; called by muse, mutect2, varscan2
- ZNF416 | c.1261C>T p.L421= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs140295213; called by muse, mutect2, varscan2
- ZNF609 | c.2037G>A p.A679= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs151162773; called by muse, mutect2, varscan2
- ZNF641 | c.333C>T p.I111= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99973341; called by muse, mutect2, varscan2
- ZXDC | c.1641C>T p.S547= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100306289; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95669606 G>A | 5'Flank (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847847 G>A | 5'Flank (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- AP001425.1 | chr21:38208189 C>T | 5'Flank (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- HMGA2 | c.250-36299C>T | Intron (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100666433; called by muse, mutect2, varscan2
- KIF1B | c.2115+6851C>T | Intron (SNP) | VAF 17/108 reads (16%) | catalogued as COSV99822384, COSV99824078; called by muse, mutect2, varscan2
- NLRP7 | c.2810+2727C>T | Intron (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100051596; called by muse, mutect2, varscan2
- PRELID3A | c.*1G>A | 3'UTR (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100426822; called by muse, mutect2
- SLIT2 | c.1463-653C>T | Intron (SNP) | VAF 19/95 reads (20%) | catalogued as COSV104384537, COSV99880630; called by muse, mutect2, varscan2
- SPG7 | c.1303+4153C>T | Intron (SNP) | VAF 43/148 reads (29%) | catalogued as rs1254641982, COSV99244535; called by muse, mutect2, varscan2
- TAF1 | c.5002-328G>A | Intron (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99334360; called by muse, mutect2, varscan2
